Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H0-01A from TCGA case TCGA-2Y-A9H0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-2Y-A9H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.671e7861-4eaf-407c-97a8-d6b8e468bd56.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eab38768-f1bf-48d4-baec-80fcbe200466

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5,529; copy number 2: 46,140; copy number 3: 5,965; copy number 4: 551; copy number 5: 1,294; copy number 6: 14; copy number 7: 8; copy number 9: 249; copy number 10: 57; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H0-01A-11D-A381-01): tumor purity 0.86, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,899,106, 1 gene: LRRC57P1.
- chr6:19,612,755–19,642,529, 3 genes: KRT18P38, UQCRFS1P3, RNU6-801P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,624 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:213,817,751–214,187,773, 6 genes, copy number 7 (within-gene range 3–7): PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775.
- chr6:16,107,622–17,382,120, 20 genes, copy number 10: MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1.
- chr6:19,143,695–19,839,080, 5 genes, copy number 12 (within-gene range 0–12): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205.
- chr6:19,837,370–23,125,087, 37 genes, copy number 10: ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P.
- chr6:29,849,550–32,763,532, 254 genes, copy number 5–9 (broad region; genes not listed).
- chr9:109,760,360–109,772,043, 1 gene, copy number 5: AL158829.1.
- chr11:83,259,097–83,423,516, 4 genes, copy number 5: CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr12:54,353,661–54,497,688, 1 gene, copy number 5 (within-gene range 2–5): AC079313.2.
- chr12:54,428,303–119,668,079, 1,253 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:31,391,675–31,637,543, 12 genes, copy number 5: RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3.
- chr17:40,553,769–40,648,654, 3 genes, copy number 6 (within-gene range 3–6): CCR7, AC004585.2, SMARCE1.
- chr17:45,620,344–46,028,334, 11 genes, copy number 6 (within-gene range 3–6): LINC02210-CRHR1, AC217774.1, AC217774.2, CRHR1, MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH.
- chr17:50,834,650–51,297,936, 17 genes, copy number 5 (within-gene range 3–5): WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18.

Autosomal genes at a single copy (total copy number 1): 5,504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
